Somatic mutation profile of tumor specimen TCGA-39-5040-01A (aliquot TCGA-39-5040-01A-21D-2122-08) from TCGA case TCGA-39-5040, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.7 years (21,790 days).
Specimen TCGA-39-5040-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0311929-6070-4159-80d3-30c84896da7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5040-11A (Solid Tissue Normal), aliquot TCGA-39-5040-11A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdcd10e0-79af-4412-92c7-fb9d595df2a2

The open-access MAF lists 539 somatic variants for this specimen: 399 protein-altering or splice-affecting, 131 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 325, Silent 131, Nonsense Mutation 25, Frame Shift Del 19, Splice Site 11, Frame Shift Ins 8, Splice Region 8, RNA 4, Intron 3, In Frame Del 2, Translation Start Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSPP1 | c.3076+1G>A p.X1026_splice (on ENST00000676605; = p.X985_splice on NM_024790.6) | Splice Site (SNP) | VAF 17/36 reads (47%) | catalogued as rs587777142, CS140101, COSV99139418; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 39/71 reads (55%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCG2 | c.475G>T p.E159* | Nonsense Mutation (SNP) | VAF 29/129 reads (22%) | catalogued as COSV99418745, COSV99419844; called by muse, mutect2, varscan2
- ABCG2 | c.474C>G p.N158K | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.5); PolyPhen benign (0.089); catalogued as rs150450599, COSV99419856; called by muse, mutect2, varscan2
- ABCG4 | c.1715+2T>A p.X572_splice | Splice Site (SNP) | VAF 96/230 reads (42%) | catalogued as COSV100266951; called by muse, mutect2, varscan2
- ACP4 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs749031762, COSV99567496; called by muse, mutect2, varscan2
- ACSBG1 | c.1511G>T p.R504L | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs747318165, COSV99357691; called by muse, mutect2, varscan2
- ACSM1 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 112/192 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.17); catalogued as COSV99533303; called by muse, mutect2, varscan2
- ADAM29 | c.1856C>A p.T619N | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV100822187; called by muse, mutect2, varscan2
- ADAMTS6 | c.1229G>T p.G410V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101125289; called by muse, mutect2, varscan2
- ADCY8 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 48/127 reads (38%) | catalogued as COSV53923813, COSV99653606; called by muse, mutect2, varscan2
- ADGRB1 | c.1214T>C p.V405A | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as COSV100030137; called by muse, mutect2, varscan2
- ADGRF5 | c.2332G>C p.D778H | Missense Mutation (SNP) | VAF 67/107 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as rs1252749175, COSV99346163; called by muse, mutect2, varscan2
- ADGRL3 | c.3710G>T p.G1237V (on ENST00000506720 / NM_001322402.2; = p.G1169V on NM_015236.6) | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101547290, COSV72229843; called by muse, mutect2, varscan2
- ALPK2 | c.2324C>A p.S775Y | Missense Mutation (SNP) | VAF 57/136 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.144); catalogued as COSV100864705; called by muse, mutect2, varscan2
- AMY2B | c.260G>T p.R87I | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100796441; called by muse, mutect2, varscan2
- AMY2B | c.391G>C p.G131R | Missense Mutation (SNP) | VAF 178/540 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100796442; called by muse, mutect2, varscan2
- ANK2 | c.11757G>T p.M3919I | Missense Mutation (SNP) | VAF 66/95 reads (69%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV100003359; called by muse, mutect2, varscan2
- ANLN | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as COSV99732677; called by muse, mutect2, varscan2
- ANXA4 | c.931A>G p.K311E | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.818); catalogued as COSV99247876; called by muse, mutect2, varscan2
- APC | c.6674C>T p.S2225F | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.998); catalogued as COSV99969374; called by muse, mutect2, varscan2
- APCDD1 | c.341G>C p.R114P | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.444); catalogued as COSV62372722; called by muse, mutect2, varscan2
- APEH | c.1706A>T p.Q569L | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV99610988; called by muse, mutect2, varscan2
- APOBR | c.1626G>A p.W542* (on ENST00000431282; = p.W551* on NM_018690.4) | Nonsense Mutation (SNP) | VAF 7/16 reads (44%) | catalogued as COSV60491130; called by muse, mutect2, varscan2
- APOC3 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as COSV99369344; called by muse, mutect2, varscan2
- ARHGAP44 | c.2399G>C p.R800P | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.769); catalogued as rs752764904, COSV99311304; called by muse, mutect2, varscan2
- ARHGAP5 | c.2781A>T p.Q927H | Missense Mutation (SNP) | VAF 43/72 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV100565622; called by muse, mutect2, varscan2
- ARMH4 | c.1471A>C p.S491R | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99958742; called by muse, mutect2, varscan2
- ASS1 | c.175-1G>T p.X59_splice | Splice Site (SNP) | VAF 72/99 reads (73%) | catalogued as COSV100752778; called by muse, mutect2, varscan2
- ATF6 | c.1068G>T p.K356N | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100909364; called by muse, mutect2
- ATP10B | c.1815C>T p.V605= | Splice Region (SNP) | VAF 113/269 reads (42%) | catalogued as COSV100515522; called by muse, mutect2, varscan2
- ATP4A | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.094); catalogued as COSV99382936; called by muse, mutect2, varscan2
- ATRNL1 | c.4120C>T p.R1374C | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs782456237, COSV100368856, COSV58094648, COSV58105578; called by muse, mutect2
- BCHE | c.1146A>T p.L382F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); catalogued as COSV100012873; called by muse, mutect2, varscan2
- BEST3 | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as COSV100437920; called by muse, mutect2, varscan2
- BOC | c.3104G>C p.R1035T | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.006); catalogued as COSV99849151; called by muse, mutect2, varscan2
- CAMK2N1 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV100907023; called by muse, mutect2, varscan2
- CCDC102B | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 49/146 reads (34%) | catalogued as COSV60137123, COSV60144836; called by muse, mutect2, varscan2
- CCDC126 | c.240G>A p.A80= | Splice Region (SNP) | VAF 18/64 reads (28%) | catalogued as rs754418462, COSV100277962, COSV56739828; called by muse, mutect2, varscan2
- CCDC40 | c.499G>A p.G167S | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as COSV99482116; called by muse, mutect2, varscan2
- CD33 | c.179G>T p.W60L | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99220692; called by muse, mutect2, varscan2
- CD6 | c.1259C>A p.A420D | Missense Mutation (SNP) | VAF 58/306 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV100533205; called by muse, mutect2, varscan2
- CD86 | c.203T>G p.V68G (on ENST00000330540 / NM_175862.5; = p.V62G on NM_006889.4) | Missense Mutation (SNP) | VAF 102/168 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100054135; called by muse, mutect2, varscan2
- CDCA4 | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100288256; called by muse, mutect2, varscan2
- CDH6 | c.1861C>A p.L621M | Missense Mutation (SNP) | VAF 44/124 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV99420281; called by muse, mutect2, varscan2
- CDT1 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs780790780, COSV99967337; called by muse, mutect2, varscan2
- CENPF | c.3405A>T p.L1135F | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT tolerated (0.14); PolyPhen benign (0.333); catalogued as COSV100871876; called by muse, mutect2, varscan2
- CFHR1 | c.402G>T p.W134C | Missense Mutation (SNP) | VAF 75/137 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100258929; called by muse, mutect2, varscan2
- CHD3 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs1208434202, COSV57877024; called by muse, mutect2, varscan2
- CHRNB3 | c.84T>A p.N28K | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV99251387; called by muse, mutect2, varscan2
- CHSY3 | c.2380G>T p.G794C | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519706; called by muse, mutect2, varscan2
- CINP | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV99392221; called by muse, mutect2, varscan2
- CLCNKB | c.1774G>T p.G592C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100989746; called by muse, mutect2, varscan2
- CLDN19 | c.327C>G p.D109E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV56417810, COSV99591702; called by muse, mutect2, varscan2
- CNNM4 | c.2102G>C p.R701P | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV100998777; called by muse, mutect2, varscan2
- CNTN2 | c.1641C>A p.D547E | Missense Mutation (SNP) | VAF 114/223 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100085333; called by muse, mutect2, varscan2
- CNTN6 | c.2231G>T p.G744V | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100611560, COSV63191186; called by muse, mutect2, varscan2
- COG6 | c.926G>T p.G309V | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100743209; called by muse, mutect2, varscan2
- COL20A1 | c.2382C>A p.S794R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV100491129; called by muse, mutect2
- COL20A1 | c.2563G>T p.A855S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV100490608, COSV100491131; called by muse, mutect2, varscan2
- COL22A1 | c.1672G>C p.E558Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.992); catalogued as rs1302816643, COSV100279922; called by muse, mutect2, varscan2
- COL3A1 | c.3538C>A p.H1180N | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV100483572, COSV58591429; called by muse, mutect2, varscan2
- COL4A3 | c.888+2T>G p.X296_splice | Splice Site (SNP) | VAF 6/78 reads (8%) | catalogued as COSV101170480; called by muse, mutect2
- COL4A5 | c.1167G>T p.G389= | Splice Region (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100087690, COSV100089095; called by muse, mutect2
- COL5A3 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779327482, COSV53418139; called by muse, mutect2, varscan2
- COL6A3 | c.6879G>T p.T2293= | Splice Region (SNP) | VAF 19/134 reads (14%) | catalogued as COSV99798523, COSV99800412; called by muse, mutect2, varscan2
- COLGALT1 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV99395214; called by muse, mutect2, varscan2
- COP1 | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 81/150 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.765); catalogued as COSV100443726; called by muse, mutect2, varscan2
- CRB1 | c.2095C>T p.H699Y | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66329019; called by muse, mutect2, varscan2
- CREG2 | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs572785251, COSV100240618; called by muse, mutect2, varscan2
- CSMD3 | c.7897G>T p.G2633W (on ENST00000297405 / NM_001363185.1; = p.G2529W on NM_052900.3) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843215; called by muse, mutect2, varscan2
- CTDSPL2 | c.1348C>T p.R450* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as COSV99527152; called by muse, mutect2, varscan2
- CTNND2 | c.2177G>T p.G726V | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58924817, COSV58934827; called by muse, mutect2, varscan2
- CXorf66 | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100983923; called by muse, mutect2, varscan2
- CYLD | c.690G>C p.L230F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV100282664; called by muse, mutect2, varscan2
- DCDC1 | c.4872G>T p.M1624I (on ENST00000597505 / NM_001367979.1; = p.M731I on NM_020869.3) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.019); catalogued as COSV100360713; called by muse, mutect2, varscan2
- DCDC1 | c.4871T>A p.M1624K (on ENST00000597505 / NM_001367979.1; = p.M731K on NM_020869.3) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.361); catalogued as COSV100360714; called by muse, mutect2, varscan2
- DDI1 | c.184G>T p.G62C | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); catalogued as COSV100160293; called by muse, mutect2
- DEFB123 | c.122G>A p.R41K | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100889859; called by muse, mutect2, varscan2
- DHX37 | c.646G>A p.V216I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100439418; called by muse, mutect2, varscan2
- DISP3 | c.1248G>T p.E416D | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV99607773, COSV99609611; called by muse, mutect2, varscan2
- DNAJC10 | c.2323A>G p.I775V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs754077716, COSV99899515; called by muse, mutect2, varscan2
- DPP7 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100857397, COSV65371418; called by muse, varscan2
- DPYSL2 | c.1714G>C p.G572R | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100234084, COSV60784944; called by muse, mutect2, varscan2
- DSCAM | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV101261178; called by muse, mutect2, varscan2
- DTNA | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99314309; called by muse, mutect2, varscan2
- DTX1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.338); catalogued as rs200220437, COSV57501747; called by muse, mutect2, varscan2
- EGFLAM | c.2745G>C p.M915I (on ENST00000354891 / NM_001205301.2; = p.M907I on NM_152403.4) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as COSV100380601; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1348044932, COSV100349322, COSV57516315; called by muse, mutect2, varscan2
- ELMO1 | c.1951C>G p.Q651E | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV100165519; called by muse, mutect2, varscan2
- EPHA6 | c.1763G>C p.R588T | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); catalogued as COSV101064902, COSV67563173; called by muse, mutect2, varscan2
- ESX1 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 66/112 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV101006490; called by muse, mutect2, varscan2
- EVPL | c.3442C>T p.L1148F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101440959; called by muse, mutect2, varscan2
- FAM114A2 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.051); catalogued as COSV100491702; called by muse, mutect2
- FAM117B | c.1391A>T p.Y464F | Missense Mutation (SNP) | VAF 45/80 reads (56%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100287798; called by muse, mutect2, varscan2
- FAM131B | c.185-1G>A p.X62_splice | Splice Site (SNP) | VAF 4/38 reads (11%) | catalogued as COSV101281847; called by muse, mutect2
- FAM180A | c.69G>T p.W23C | Missense Mutation (SNP) | VAF 62/280 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV100647325; called by muse, mutect2, varscan2
- FAM71C | c.699del p.Y234Ifs*6 | Frame Shift Del (DEL) | VAF 32/134 reads (24%) | catalogued as rs1567561959; called by mutect2, pindel, varscan2
- FBXO24 | c.403G>A p.G135S (on ENST00000241071 / NM_033506.3; = p.G173S on NM_012172.5) | Missense Mutation (SNP) | VAF 72/134 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs200639966, COSV99575556; called by muse, mutect2, varscan2
- FBXO28 | c.376A>T p.R126W | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100837477; called by muse, mutect2, varscan2
- FBXW7 | c.1567G>T p.V523L (on ENST00000281708 / NM_001349798.2; = p.V443L on NM_018315.5) | Missense Mutation (SNP) | VAF 77/130 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.416); catalogued as COSV99659660; called by muse, mutect2, varscan2
- FCER1A | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 75/116 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100929295, COSV63666650; called by muse, mutect2, varscan2
- FLACC1 | c.942+1G>T p.X314_splice | Splice Site (SNP) | VAF 12/136 reads (9%) | catalogued as COSV99630687; called by muse, mutect2
- FLG | c.1299C>A p.D433E | Missense Mutation (SNP) | VAF 101/539 reads (19%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.992); catalogued as rs759739224, COSV64250607; called by muse, mutect2, varscan2
- FLNC | c.5744C>A p.T1915N | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as COSV100368551; called by muse, mutect2, varscan2
- FMN2 | c.3367C>T p.P1123S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); catalogued as COSV100144887, COSV100146705; called by muse, mutect2, varscan2
- FMO2 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0.322); catalogued as rs183698382, COSV52946841; called by muse, mutect2, varscan2
- FMO2 | c.1012C>A p.L338I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV52947886; called by muse, mutect2, varscan2
- FOXH1 | c.896C>A p.S299Y | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100023926; called by muse, mutect2, varscan2
- GABRB2 | c.693G>T p.R231S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99196415; called by muse, mutect2, varscan2
- GABRB2 | c.692G>T p.R231M | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50941683, COSV99196418; called by muse, mutect2, varscan2
- GALNT18 | c.1801G>T p.V601F | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.049); catalogued as COSV99925468, COSV99925974; called by muse, mutect2, varscan2
- GAREM1 | c.804_805insT p.H269Sfs*4 | Frame Shift Ins (INS) | VAF 53/174 reads (30%) | catalogued as COSV99331167; called by mutect2, pindel, varscan2
- GDPD1 | c.457A>G p.K153E | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99405256; called by muse, mutect2, varscan2
- GGN | c.1577G>C p.R526P | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99287618; called by muse, mutect2
- GIMAP4 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99751030; called by muse, mutect2, varscan2
- GMIP | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.125); catalogued as rs915139066, COSV99179473; called by muse, mutect2, varscan2
- GNAZ | c.731T>A p.M244K | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV99321080; called by muse, mutect2, varscan2
- GNAZ | c.732G>T p.M244I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV99321081; called by muse, mutect2, varscan2
- GPA33 | c.883A>T p.R295W | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV100901197; called by muse, mutect2, varscan2
- GPA33 | c.882G>T p.E294D | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100901199; called by muse, mutect2, varscan2
- GPR151 | c.1137G>C p.E379D | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99695144; called by muse, mutect2
- GRID1 | c.967C>G p.L323V | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV100025735, COSV60026548; called by muse, mutect2, varscan2
- GRIN2D | c.2221G>T p.V741L | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54379241, COSV99616813; called by muse, mutect2, varscan2
- GRXCR1 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT tolerated (0.77); PolyPhen benign (0.237); catalogued as rs757243306, COSV101295731; called by muse, mutect2
- HADH | c.106G>T p.G36W | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100531508; called by muse, mutect2
- HAS2 | c.1632A>C p.Q544H | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV100392087; called by muse, varscan2
- HDAC9 | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.42); PolyPhen benign (0.057); catalogued as COSV101286922; called by muse, varscan2
- HDLBP | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100191504; called by muse, mutect2, varscan2
- HECW1 | c.2531G>T p.R844L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101224138; called by muse, mutect2, varscan2
- HGF | c.2110G>T p.G704C | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV99738038; called by muse, mutect2, varscan2
- HIVEP2 | c.2140A>T p.S714C | Missense Mutation (SNP) | VAF 87/140 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV99174958; called by muse, mutect2, varscan2
- HOXC10 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100329140; called by muse, mutect2, varscan2
- HSPG2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs570733273, COSV101012977; called by muse, mutect2, varscan2
- IGFN1 | c.1978G>T p.G660C (on ENST00000295591 / NM_001367841.1; = p.G3117C on NM_001164586.2) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.173); catalogued as COSV99813159; called by muse, mutect2, varscan2
- IGHV1-45 | c.167T>A p.V56E | Missense Mutation (SNP) | VAF 71/124 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs782431139; called by muse, mutect2, varscan2
- IGSF1 | c.3860C>A p.P1287H | Missense Mutation (SNP) | VAF 76/138 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100812236; called by muse, mutect2, varscan2
- IL7R | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.315); catalogued as COSV100286503; called by muse, mutect2, varscan2
- ITGA4 | c.1166del p.G389Efs*39 | Frame Shift Del (DEL) | VAF 12/94 reads (13%) | catalogued as COSV52001350; called by mutect2, pindel, varscan2
- ITGB1 | c.1364A>T p.E455V | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV100171898; called by muse, mutect2, varscan2
- ITPRID1 | c.2395C>A p.H799N | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.498); catalogued as COSV100087181; called by muse, varscan2
- ITPRID1 | c.2411A>G p.H804R | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.359); catalogued as COSV100087184; called by muse, varscan2
- ITPRID2 | c.2119A>C p.N707H | Missense Mutation (SNP) | VAF 45/79 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100238599; called by muse, mutect2, varscan2
- JCAD | c.1136A>G p.K379R | Missense Mutation (SNP) | VAF 72/141 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.038); catalogued as COSV100948517; called by muse, mutect2, varscan2
- JMJD1C | c.3130G>T p.G1044C | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100550744; called by muse, mutect2, varscan2
- KAT2B | c.1441A>G p.R481G | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99769693; called by muse, mutect2, varscan2
- KCNJ2 | c.649C>A p.L217I | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs1218827971, COSV54664422, COSV99696475; called by muse, mutect2, varscan2
- KCNU1 | c.2468C>T p.T823I | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV67760522; called by muse, mutect2, varscan2
- KCNV1 | c.1081T>A p.S361T | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV99819344; called by muse, mutect2, varscan2
- KIR3DL1 | c.356-2A>G p.X119_splice | Splice Site (SNP) | VAF 69/498 reads (14%) | catalogued as rs764791039; called by muse, mutect2, varscan2
- KLHL20 | c.1067G>T p.C356F | Missense Mutation (SNP) | VAF 82/138 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV99268598; called by muse, mutect2, varscan2
- KLHL30 | c.868C>A p.P290T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as rs548766837, COSV59978481; called by muse, mutect2, varscan2
- KMT2C | c.2872-1G>T p.X958_splice | Splice Site (SNP) | VAF 30/221 reads (14%) | catalogued as COSV51460063, COSV51479683; called by muse, mutect2, varscan2
- KNDC1 | c.5131G>A p.G1711S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.434); catalogued as rs759091302, COSV58832523; called by muse, mutect2, varscan2
- KRT3 | c.1182G>T p.Q394H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV100527162, COSV58816732; called by muse, mutect2
- KRT35 | c.185G>T p.R62M | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as COSV99877865; called by muse, mutect2, varscan2
- KRT83 | c.921G>C p.E307D | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV99531751, COSV99531822; called by muse, mutect2, varscan2
- KRTAP19-4 | c.92G>A p.S31N | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.029); catalogued as COSV100478557; called by muse, mutect2, varscan2
- KRTAP6-1 | c.46G>T p.G16W | Missense Mutation (SNP) | VAF 91/201 reads (45%) | PolyPhen probably damaging (1); catalogued as COSV100228824; called by muse, mutect2, varscan2
- LAMA2 | c.7781G>T p.R2594L | Missense Mutation (SNP) | VAF 42/79 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as COSV101370725; called by muse, mutect2, varscan2
- LATS2 | c.2023G>T p.G675W | Missense Mutation (SNP) | VAF 58/87 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66874351; called by muse, mutect2, varscan2
- LDB3 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53949831, COSV99555718; called by muse, mutect2, varscan2
- LENG8 | c.1574G>T p.R525L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.218); catalogued as rs762102522, COSV100457968; called by muse, mutect2, varscan2
- LIN9 | c.300G>T p.W100C (on ENST00000366808 / NM_001270410.2; = p.W45C on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/143 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.917); catalogued as COSV100067861; called by muse, mutect2, varscan2
- LMX1A | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 133/270 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs909983869, COSV54218563, COSV99672908; called by muse, mutect2, varscan2
- LPAR4 | c.753C>G p.I251M | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101425150; called by muse, mutect2, varscan2
- LRBA | c.6806T>C p.L2269S | Missense Mutation (SNP) | VAF 47/81 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100841972; called by muse, mutect2, varscan2
- LRP1B | c.1682T>C p.L561S | Missense Mutation (SNP) | VAF 116/224 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as COSV101259243; called by muse, mutect2, varscan2
- LRP3 | c.1289G>T p.C430F | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99472446; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.946C>A p.Q316K | Missense Mutation (SNP) | VAF 229/340 reads (67%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV101010839; called by muse, mutect2, varscan2
- LYPD5 | c.668C>A p.T223N (on ENST00000377950 / NM_001031749.3; = p.T180N on NM_182573.2) | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV100935276; called by muse, mutect2, varscan2
- LYZL2 | c.391C>A p.R131S (on ENST00000375318; = p.R85S on NM_183058.3) | Missense Mutation (SNP) | VAF 73/137 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100940627; called by muse, mutect2, varscan2
- MACF1 | c.10891G>T p.G3631* (on ENST00000372915; = p.G1564* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 34/118 reads (29%) | catalogued as COSV99246104; called by muse, mutect2, varscan2
- MAGEC3 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV100025906; called by muse, mutect2, varscan2
- MAL | c.99C>A p.F33L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100015849, COSV59432790; called by muse, mutect2, varscan2
- MAML2 | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101594169; called by muse, mutect2, varscan2
- MAP3K6 | c.841C>A p.L281M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100709393; called by muse, mutect2
- MAPK8IP2 | c.2342G>C p.R781P | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99151348; called by muse, varscan2
- MAST2 | c.234A>G p.I78M | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.486); catalogued as COSV100788634; called by muse, mutect2, varscan2
- METTL16 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV99563696, COSV99563839; called by muse, mutect2, varscan2
- MISP | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT tolerated (0.2); PolyPhen benign (0.019); catalogued as COSV99297062; called by muse, mutect2, varscan2
- MLF2 | c.588G>A p.W196* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99180111; called by muse, mutect2, varscan2
- MMRN1 | c.1797C>A p.C599* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV99307545; called by muse, mutect2, varscan2
- MSH4 | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV54207942; called by muse, mutect2, varscan2
- MTMR6 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as COSV101110825; called by muse, mutect2, varscan2
- MUC5AC | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.01); catalogued as COSV100650660; called by muse, mutect2, varscan2
- MYO1H | c.1763T>C p.L588P | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100183842; called by muse, mutect2, varscan2
- MYRF | c.3011A>G p.Q1004R (on ENST00000278836 / NM_001127392.3; = p.Q969R on NM_013279.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV99607628; called by muse, mutect2
- MYT1L | c.76C>G p.Q26E | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as COSV101221145; called by muse, mutect2, varscan2
- NALCN | c.4378C>G p.Q1460E | Missense Mutation (SNP) | VAF 40/57 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs1335710703, COSV51946337; called by muse, mutect2, varscan2
- NALCN | c.645G>T p.G215= | Splice Region (SNP) | VAF 42/72 reads (58%) | catalogued as COSV99216911; called by muse, mutect2, varscan2
- NAV3 | c.3493A>T p.N1165Y | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV57076472; called by muse, mutect2, varscan2
- NAXD | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 42/68 reads (62%) | catalogued as COSV100010626; called by muse, mutect2, varscan2
- NCAPG2 | c.1656G>C p.R552S | Missense Mutation (SNP) | VAF 47/207 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99317454; called by muse, mutect2, varscan2
- NCOA2 | c.2696C>A p.A899D | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.236); catalogued as COSV99145002; called by muse, mutect2
- NCOR1 | c.3128C>T p.T1043I | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs376522360; called by muse, mutect2, varscan2
- NCOR2 | c.2807G>T p.R936L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100657738; called by muse, mutect2, varscan2
- NEDD1 | c.806G>T p.R269L | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.341); catalogued as rs748497881, COSV57146708, COSV99901221; called by muse, mutect2, varscan2
- NEU2 | c.710G>T p.R237I | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749067551, COSV99290684; called by muse, mutect2, varscan2
- NF2 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 43/63 reads (68%) | catalogued as COSV58525444; called by muse, mutect2, varscan2
- NGLY1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1365110057, COSV99770783; called by muse, mutect2, varscan2
- NINJ2 | c.194C>A p.T65N | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV56756529, COSV99843425; called by muse, mutect2, varscan2
- NLRC3 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100073208; called by muse, mutect2, varscan2
- NOS1 | c.3859G>T p.G1287W | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100501162; called by muse, mutect2, varscan2
- NPAS4 | c.151C>A p.R51S | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100215170; called by muse, mutect2, varscan2
- NPY | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs1388032616, COSV54215104; called by muse, mutect2, varscan2
- NRXN1 | c.4237C>A p.L1413M | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV60524852; called by muse, mutect2, varscan2
- NRXN1 | c.1418G>T p.C473F | Missense Mutation (SNP) | VAF 84/169 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100456341; called by muse, mutect2, varscan2
- ODAM | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 168/266 reads (63%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as COSV101258099; called by muse, mutect2, varscan2
- OPN1SW | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs373496991; called by muse, mutect2, varscan2
- OR2A5 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV101278812; called by muse, mutect2, varscan2
- OR2M3 | c.341T>A p.L114H | Missense Mutation (SNP) | VAF 91/518 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101513495, COSV71758835; called by muse, mutect2
- OR4A16 | c.229C>A p.P77T | Missense Mutation (SNP) | VAF 55/217 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV100125356; called by muse, mutect2, varscan2
- OR51D1 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62914189; called by muse, mutect2, varscan2
- OR5AR1 | c.723C>A p.C241* | Nonsense Mutation (SNP) | VAF 42/111 reads (38%) | catalogued as COSV100265741, COSV57254000; called by muse, mutect2, varscan2
- OR5B3 | c.466A>T p.I156F | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.098); catalogued as COSV100512049; called by muse, mutect2, varscan2
- OR5J2 | c.915A>G p.I305M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV100399190; called by muse, mutect2
- OR6C6 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.077); catalogued as rs1390215043, COSV100626513; called by muse, mutect2, varscan2
- OR7C2 | c.284C>G p.A95G | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.027); catalogued as COSV99934601; called by muse, mutect2, varscan2
- OSBPL3 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.964); catalogued as COSV100514412; called by muse, mutect2, varscan2
- P2RY13 | c.230C>A p.T77N | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.123); catalogued as COSV99854224; called by muse, mutect2
- P4HA3 | c.841G>A p.V281M | Missense Mutation (SNP) | VAF 110/241 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs748116772, COSV100525835; called by muse, mutect2, varscan2
- PADI2 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100971046; called by muse, mutect2
- PAX6 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as CD083337, COSV99570714; called by muse, mutect2, varscan2
- PCDH11Y | c.2685G>T p.Q895H (on ENST00000400457 / NM_032973.2; = p.Q884H on NM_032971.3) | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV99292328; called by muse, mutect2, varscan2
- PCDH15 | c.5192C>T p.A1731V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated, low confidence (0.06); catalogued as rs1564510930, COSV100905357; called by muse, mutect2
- PCDH19 | c.3038G>A p.R1013Q (on ENST00000373034 / NM_001184880.2; = p.R965Q on NM_020766.3) | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs867719291, COSV99720508; called by muse, mutect2, varscan2
- PCDH8 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100131951; called by muse, mutect2, varscan2
- PCDHA8 | c.1624G>T p.V542L | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.094); catalogued as rs781992990, COSV100969926, COSV65324031; called by muse, mutect2, varscan2
- PCDHGA1 | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as COSV100966041; called by muse, mutect2, varscan2
- PCDHGA9 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.213); catalogued as COSV99543903; called by muse, mutect2, varscan2
- PCDHGB6 | c.1447C>A p.L483I | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV99543908; called by muse, mutect2, varscan2
- PCLO | c.13833G>T p.V4611= | Splice Region (SNP) | VAF 7/19 reads (37%) | catalogued as rs965918018, COSV100436037; called by muse, mutect2, varscan2
- PCSK2 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 123/177 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV99360351; called by muse, mutect2, varscan2
- PDCD6IP | c.2033A>T p.N678I | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100219067; called by muse, mutect2, varscan2
- PIK3C2G | c.4288G>T p.D1430Y (on ENST00000676171; = p.D1389Y on NM_004570.5) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV56825580, COSV56829533; called by muse, mutect2, varscan2
- PKP1 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.35); PolyPhen benign (0.026); catalogued as rs376443293, COSV99825592; called by muse, varscan2
- PLCB1 | c.2933C>A p.S978* | Nonsense Mutation (SNP) | VAF 19/158 reads (12%) | catalogued as COSV100571805; called by muse, mutect2, varscan2
- PLCE1 | c.1469C>A p.S490Y | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV99596485; called by muse, mutect2, varscan2
- PLOD3 | c.1852G>T p.G618W | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99778190; called by muse, mutect2, varscan2
- PLXNC1 | c.1184G>C p.G395A | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.124); catalogued as COSV99312507, COSV99312535, COSV99313564; called by muse, mutect2, varscan2
- PMEPA1 | c.716A>G p.Y239C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.031); catalogued as COSV99671978; called by muse, mutect2
- PNMA3 | c.340A>G p.R114G | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (1); PolyPhen possibly damaging (0.801); catalogued as COSV100937651; called by muse, mutect2, varscan2
- PRAG1 | c.241A>T p.K81* | Nonsense Mutation (SNP) | VAF 35/64 reads (55%) | catalogued as COSV100422619; called by muse, mutect2, varscan2
- PRDM16 | c.378C>A p.F126L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99578186; called by muse, mutect2, varscan2
- PRG4 | c.4127A>G p.Y1376C | Missense Mutation (SNP) | VAF 91/173 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs562730445, COSV63356400; called by muse, mutect2, varscan2
- PSG1 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 139/452 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs753031944, COSV99741061; called by muse, mutect2, varscan2
- PTPRO | c.3003C>A p.Y1001* (on ENST00000281171 / NM_030667.3; = p.Y973* on NM_002848.4) | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | catalogued as COSV55524133, COSV99841369; called by muse, mutect2, varscan2
- PTPRZ1 | c.963C>A p.D321E | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV101100617; called by muse, mutect2, varscan2
- PTPRZ1 | c.2571T>A p.H857Q | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV101100618; called by muse, mutect2, varscan2
- PTPRZ1 | c.2572G>T p.A858S | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.433); catalogued as COSV101100621; called by muse, mutect2, varscan2
- RAG1 | c.2674A>G p.M892V | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.817); catalogued as COSV100201074; called by muse, mutect2, varscan2
- RAI14 | c.2590G>C p.A864P | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.244); catalogued as COSV99464200; called by muse, mutect2, varscan2
- RASGRF2 | c.732A>T p.R244S | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99429947; called by muse, mutect2, varscan2
- RBBP5 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 54/246 reads (22%) | catalogued as COSV52707161; called by muse, mutect2, varscan2
- RBM26 | c.2608C>T p.R870* (on ENST00000438737 / NM_001366735.2; = p.R843* on NM_022118.5) | Nonsense Mutation (SNP) | VAF 8/86 reads (9%) | catalogued as COSV99936438; called by muse, varscan2
- RBM6 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1407213777, COSV99805777; called by muse, mutect2
- RC3H2 | c.3520G>A p.E1174K | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV100605919; called by muse, mutect2, varscan2
- RELL2 | c.467C>A p.P156H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV51839034, COSV99781450; called by muse, mutect2, varscan2
- RERGL | c.314C>A p.P105Q | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.356); catalogued as COSV99968027; called by muse, mutect2, varscan2
- REST | c.2272A>C p.K758Q | Missense Mutation (SNP) | VAF 283/486 reads (58%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.001); catalogued as COSV100471238; called by muse, mutect2, varscan2
- RIMS2 | c.1021C>T p.R341C (on ENST00000666250 / NM_001348490.2; = p.R149C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766129122, COSV51653199; called by muse, mutect2, varscan2
- RIMS2 | c.4619A>T p.Q1540L (on ENST00000666250 / NM_001348490.2; = p.Q1111L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99182364; called by muse, mutect2, varscan2
- ROBO1 | c.4124del p.G1375Afs*42 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs869034500; called by mutect2, pindel, varscan2
- ROBO4 | c.491A>T p.H164L | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV100127775; called by muse, mutect2, varscan2
- RP1L1 | c.2326A>T p.I776L | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs1412966122, COSV101223493; called by muse, mutect2, varscan2
- RTF2 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs762651242, COSV99196536; called by muse, mutect2, varscan2
- RXFP1 | c.2073G>T p.M691I | Missense Mutation (SNP) | VAF 46/81 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100314078; called by muse, mutect2, varscan2
- RYR2 | c.7630C>A p.L2544I | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV100772131; called by muse, mutect2, varscan2
- SACS | c.13015G>T p.D4339Y | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101207605; called by muse, mutect2, varscan2
- SACS | c.12419G>A p.G4140E | Missense Mutation (SNP) | VAF 57/100 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV101207606; called by muse, mutect2, varscan2
- SALL1 | c.3556T>A p.W1186R | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99179359; called by muse, mutect2, varscan2
- SATB1 | c.1256C>G p.S419C | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100113380; called by muse, mutect2, varscan2
- SCARA5 | c.1310G>T p.R437L | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as COSV100720683; called by muse, mutect2, varscan2
- SCN1A | c.1420A>T p.S474C | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.707); catalogued as COSV100321419; called by muse, mutect2, varscan2
- SEC24B | c.1816C>G p.R606G | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs993566753, COSV54498341; called by muse, mutect2
- SELPLG | c.586C>G p.P196A | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.244); catalogued as COSV99947582; called by muse, mutect2, varscan2
- SEMG2 | c.410A>G p.H137R | Missense Mutation (SNP) | VAF 78/118 reads (66%) | SIFT tolerated (0.75); PolyPhen benign (0.009); catalogued as rs759912660, COSV101034198; called by muse, mutect2, varscan2
- SERGEF | c.122A>C p.Q41P | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.588); catalogued as COSV99787633; called by muse, mutect2, varscan2
- SGCD | c.139G>T p.V47L (on ENST00000435422 / NM_001128209.2; = p.V48L on NM_000337.5) | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.675); catalogued as rs556208970, COSV100550777; called by muse, mutect2, varscan2
- SLC22A25 | c.556G>C p.V186L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.091); catalogued as COSV100123537, COSV100123843; called by muse, mutect2, varscan2
- SLC22A5 | c.1465T>G p.F489V | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV99810117; called by muse, mutect2, varscan2
- SLC27A6 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.115); catalogued as COSV99323278; called by muse, mutect2, varscan2
- SLC35G3 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 10/295 reads (3%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.967); catalogued as COSV99269043; called by muse, mutect2
- SLC39A12 | c.1679G>T p.G560V (on ENST00000377369 / NM_001145195.2; = p.G523V on NM_152725.3) | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101070107; called by muse, mutect2, varscan2
- SLC4A1 | c.1447G>T p.G483C | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99293575; called by muse, mutect2, varscan2
- SLC5A8 | c.568_569insC p.V190Afs*31 | Frame Shift Ins (INS) | VAF 45/135 reads (33%) | catalogued as COSV101610582; called by mutect2, pindel, varscan2
- SLC7A9 | c.808A>C p.M270L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99195443; called by muse, mutect2, varscan2
- SLCO1B1 | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99918896; called by muse, mutect2, varscan2
- SLX4 | c.5012A>G p.H1671R | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99568382; called by muse, mutect2, varscan2
- SMARCA4 | c.3404G>C p.R1135P | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758997, COSV60787834; called by muse, mutect2
- SMC6 | c.679A>T p.M227L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.017); catalogued as COSV100705308; called by muse, mutect2, varscan2
- SOCS5 | c.733A>T p.T245S | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100125414; called by muse, mutect2, varscan2
- SORBS1 | c.1360+1G>A p.X454_splice | Splice Site (SNP) | VAF 21/108 reads (19%) | catalogued as rs1199967606, COSV99528685; called by muse, mutect2, varscan2
- SP140 | c.2461C>T p.Q821* | Nonsense Mutation (SNP) | VAF 26/162 reads (16%) | catalogued as COSV100613958; called by muse, mutect2, varscan2
- SPAM1 | c.1015T>A p.W339R | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99773300; called by muse, mutect2, varscan2
- SPEF2 | c.1077G>C p.K359N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99214685; called by muse, mutect2, varscan2
- SPHKAP | c.1894A>T p.T632S | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV100764364, COSV99048067; called by muse, mutect2, varscan2
- SRRM2 | c.4198C>A p.Q1400K | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100071273, COSV57076112; called by muse, mutect2
- STARD4 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV99685379; called by muse, mutect2, varscan2
- STPG3 | c.335C>A p.P112Q | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100546999; called by muse, mutect2, varscan2
- SVEP1 | c.3013G>C p.G1005R | Missense Mutation (SNP) | VAF 78/105 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1016946850, COSV100238768; called by muse, mutect2, varscan2
- SYNE1 | c.20802A>T p.E6934D (on ENST00000367255 / NM_182961.4; = p.E6863D on NM_033071.3) | Missense Mutation (SNP) | VAF 60/81 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.888); catalogued as COSV99574421; called by muse, mutect2, varscan2
- SYNPO2 | c.2968C>G p.Q990E | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.96); PolyPhen benign (0.012); catalogued as COSV100206218, COSV61116056; called by muse, mutect2, varscan2
- SYT3 | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100144252; called by muse, mutect2, varscan2
- TAC1 | c.173G>T p.R58I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100071192, COSV100071211; called by muse, mutect2, varscan2
- TAS2R60 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60331824; called by muse, mutect2, varscan2
- TBC1D15 | c.1659G>T p.W553C | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100042130; called by muse, mutect2, varscan2
- TECTA | c.4374G>T p.Q1458H | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99881037; called by muse, mutect2
- TECTA | c.4376G>T p.C1459F | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV99881038; called by muse, mutect2
- TFAP2D | c.296A>T p.Q99L | Missense Mutation (SNP) | VAF 64/97 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV99146740; called by muse, mutect2, varscan2
- TG | c.6376G>T p.V2126F | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.282); catalogued as COSV99602471; called by muse, mutect2, varscan2
- TG | c.7223G>T p.R2408L | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as rs747673148, COSV55066416, COSV99602473; called by muse, mutect2, varscan2
- TIAM1 | c.1848G>T p.M616I | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99737881; called by muse, mutect2, varscan2
- TMEM139 | c.473G>T p.R158I | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV60083258; called by muse, mutect2, varscan2
- TMEM200A | c.893G>T p.C298F | Missense Mutation (SNP) | VAF 71/115 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99759747; called by muse, mutect2, varscan2
- TMEM200B | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100549234; called by muse, varscan2
- TNIP3 | c.355C>G p.R119G | Missense Mutation (SNP) | VAF 151/242 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as COSV99284707; called by muse, mutect2, varscan2
- TNN | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 71/103 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99512636; called by muse, mutect2, varscan2
- TNNT3 | c.745G>T p.A249S (on ENST00000397301 / NM_001367846.1; = p.A238S on NM_006757.4) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.062); catalogued as COSV99548690; called by muse, mutect2
- TNR | c.1990G>T p.V664F | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV99690855; called by muse, mutect2, varscan2
- TOPORS | c.454G>T p.V152L | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV100745196; called by muse, mutect2, varscan2
- TRHR | c.1114G>T p.V372F | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV100305005; called by muse, mutect2, varscan2
- TRIM27 | c.1223C>G p.A408G | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.939); catalogued as COSV101019426; called by muse, mutect2, varscan2
- TRIO | c.4059C>T p.N1353= | Splice Region (SNP) | VAF 25/53 reads (47%) | catalogued as COSV100710771; called by muse, mutect2, varscan2
- TRIO | c.4229A>T p.Q1410L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as COSV100710774; called by muse, mutect2, varscan2
- TRPC5 | c.2470del p.Q824Kfs*81 | Frame Shift Del (DEL) | VAF 54/111 reads (49%) | catalogued as COSV99459911; called by mutect2, pindel, varscan2
- TRPM1 | c.4568T>A p.L1523Q | Missense Mutation (SNP) | VAF 140/231 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.288); catalogued as COSV99856441; called by muse, mutect2, varscan2
- TSHZ2 | c.1152G>T p.E384D | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100296567; called by muse, mutect2
- TTC14 | c.1686T>G p.D562E | Missense Mutation (SNP) | VAF 21/266 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.32); catalogued as COSV99870221; called by muse, mutect2
- TTC24 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs1420437310, COSV100964358, COSV104427643; called by muse, mutect2
- TTC4 | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV100988458; called by muse, mutect2
- TTN | c.100879G>A p.E33627K (on ENST00000591111; = p.E26203K on NM_003319.4) | Missense Mutation (SNP) | VAF 45/65 reads (69%) | PolyPhen benign (0.003); catalogued as rs1010179080, COSV100623936; called by muse, mutect2, varscan2
- TTN | c.86170G>T p.E28724* (on ENST00000591111; = p.E21300* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 11/187 reads (6%) | catalogued as COSV100623940; called by muse, mutect2
- TTN | c.38225G>T p.G12742V (on ENST00000591111; = p.G5318V on NM_003319.4) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | PolyPhen benign (0.062); catalogued as COSV100623944; called by muse, mutect2, varscan2
- TTN | c.38224G>T p.G12742C (on ENST00000591111; = p.G5318C on NM_003319.4) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | PolyPhen benign (0.386); catalogued as COSV100623947; called by muse, mutect2, varscan2
- TTN | c.20662G>T p.G6888W (on ENST00000591111; = p.G5961W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | PolyPhen probably damaging (1); catalogued as COSV100623950; called by muse, mutect2, varscan2
- TXK | c.1277C>A p.A426D | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV99972707; called by muse, mutect2, varscan2
- UBC | c.1683G>C p.K561N | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100299077, COSV60058297; called by muse, mutect2, varscan2
- UBR5 | c.5715C>G p.S1905R | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV99641901; called by muse, mutect2
- UGT2B11 | c.1579A>T p.K527* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV71424014; called by muse, mutect2
- UGT2B28 | c.1579A>T p.K527* | Nonsense Mutation (SNP) | VAF 42/69 reads (61%) | catalogued as COSV100158967; called by muse, mutect2, varscan2
- UGT8 | c.234C>G p.N78K | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV100179307; called by muse, mutect2
- UNC79 | c.3379T>G p.C1127G (on ENST00000393151 / NM_001346218.2; = p.C950G on NM_020818.5) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99829314; called by muse, mutect2, varscan2
- USH2A | c.173G>A p.C58Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100239877; called by muse, mutect2, varscan2
- VCAN | c.845A>T p.E282V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99426835; called by muse, mutect2, varscan2
- VNN1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 12/16 reads (75%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100907803; called by muse, mutect2
- VSTM2A | c.192G>C p.W64C | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs750994528, COSV100173274; called by muse, mutect2, varscan2
- WASF3 | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0.441); catalogued as COSV100099256; called by muse, mutect2, varscan2
- WDR45B | c.56A>T p.N19I | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101124462; called by muse, mutect2, varscan2
- WDR72 | c.1640A>G p.K547R | Missense Mutation (SNP) | VAF 83/142 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100854934; called by muse, mutect2, varscan2
- WNT7A | c.432C>G p.D144E | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748092973, COSV99541587; called by muse, mutect2, varscan2
- XIRP2 | c.4339G>T p.E1447* (on ENST00000628543; = p.E1622* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV54688251; called by muse, mutect2, varscan2
- XIRP2 | c.7267C>A p.L2423I (on ENST00000628543; = p.L2598I on NM_152381.6) | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV54686063; called by muse, mutect2, varscan2
- ZFHX4 | c.8033C>G p.P2678R | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50570626, COSV50623722, COSV51437950; called by muse, mutect2, varscan2
- ZFHX4 | c.8612C>A p.P2871Q | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50867751; called by muse, mutect2, varscan2
- ZNF214 | c.1681A>G p.K561E | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV99547579; called by muse, mutect2
- ZNF329 | c.1517G>T p.S506I | Missense Mutation (SNP) | VAF 205/356 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100798799; called by muse, mutect2, varscan2
- ZNF366 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.425); catalogued as rs1027425393, COSV100574383; called by muse, mutect2, varscan2
- ZNF518B | c.943G>C p.V315L | Missense Mutation (SNP) | VAF 71/154 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV100456818; called by muse, mutect2, varscan2
- ZNF536 | c.1117C>A p.H373N | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100835605; called by muse, mutect2
- ZNF536 | c.3746C>A p.P1249Q | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.154); catalogued as COSV100835606; called by muse, mutect2, varscan2
- ZNF608 | c.3169G>T p.A1057S | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100102259; called by muse, mutect2, varscan2
- ZNF615 | c.2101A>G p.K701E | Missense Mutation (SNP) | VAF 73/223 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.17); catalogued as COSV100943913; called by muse, mutect2, varscan2
- ZNF615 | c.745G>T p.D249Y | Missense Mutation (SNP) | VAF 68/270 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100943915; called by muse, mutect2, varscan2
- ZNF639 | c.960G>T p.Q320H | Missense Mutation (SNP) | VAF 95/176 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100418469; called by muse, mutect2, varscan2
- ZNF682 | c.804G>C p.W268C | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.06); catalogued as COSV100653333; called by muse, mutect2, varscan2
- ZNF687 | c.316G>T p.G106W | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as rs746046631, COSV100133950, COSV60678468; called by muse, mutect2, varscan2
- ZNF766 | c.1099A>T p.K367* | Nonsense Mutation (SNP) | VAF 23/51 reads (45%) | catalogued as COSV100765415, COSV63009319; called by muse, mutect2, varscan2
- ZRANB2 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99639648; called by muse, mutect2, varscan2
- ZSCAN9 | c.240G>T p.W80C | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV99356549; called by muse, mutect2, varscan2
- ABCC6 | c.2082del p.Y695Tfs*14 | Frame Shift Del (DEL) | VAF 27/54 reads (50%) | called by mutect2, pindel, varscan2
- ATP2B2 | c.463del p.A155Pfs*59 | Frame Shift Del (DEL) | VAF 45/218 reads (21%) | called by mutect2, pindel, varscan2
- BCORL1 | c.4650_4655del p.E1550_G1551del | In Frame Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- C11orf87 | c.133_149del p.T45Gfs*38 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- CDK18 | c.746_756+14del p.X249_splice (on ENST00000506784 / NM_212503.3; = p.X219_splice on NM_002596.4) | Splice Site (DEL) | VAF 16/147 reads (11%) | called by mutect2, pindel
- DMD | c.8087dup p.D2697Gfs*13 | Frame Shift Ins (INS) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- ESPL1 | c.6259dup p.A2087Gfs*66 | Frame Shift Ins (INS) | VAF 10/76 reads (13%) | called by mutect2, pindel, varscan2
- F5 | c.1668_1670del p.S556_W557delinsR | In Frame Del (DEL) | VAF 32/182 reads (18%) | called by mutect2, pindel, varscan2
- GABRA6 | c.544del p.S182Vfs*15 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel
- GSTT2B | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0.087); called by mutect2, varscan2
- HSDL2 | c.259_262del p.K87Pfs*12 | Frame Shift Del (DEL) | VAF 59/100 reads (59%) | called by mutect2, pindel, varscan2
- IGKV3-11 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- LRRK2 | c.1493dup p.L498Ffs*32 | Frame Shift Ins (INS) | VAF 12/80 reads (15%) | called by mutect2, pindel, varscan2
- MRC1 | c.4121-1G>C p.X1374_splice | Splice Site (SNP) | VAF 65/294 reads (22%) | called by muse, mutect2, varscan2
- MYOM3 | c.742del p.R248Afs*30 | Frame Shift Del (DEL) | VAF 36/284 reads (13%) | called by mutect2, pindel, varscan2
- PAOX | c.836dup p.A280Gfs*14 | Frame Shift Ins (INS) | VAF 11/85 reads (13%) | called by mutect2, pindel, varscan2
- PARD3 | c.3116del p.G1039Vfs*3 | Frame Shift Del (DEL) | VAF 51/167 reads (31%) | called by mutect2, pindel, varscan2
- PCDHGB5 | c.1787A>C p.H596P | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PDE10A | c.1591del p.V531Sfs*3 | Frame Shift Del (DEL) | VAF 47/89 reads (53%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.11909del p.S3970Mfs*9 | Frame Shift Del (DEL) | VAF 29/113 reads (26%) | called by mutect2, pindel, varscan2
- PLCL1 | c.2566del p.A856Hfs*8 | Frame Shift Del (DEL) | VAF 38/85 reads (45%) | called by mutect2, pindel, varscan2
- PRSS22 | c.544del p.S182Afs*17 | Frame Shift Del (DEL) | VAF 32/57 reads (56%) | called by mutect2, pindel, varscan2
- PTPRN | c.2154del p.Y719Tfs*33 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by mutect2, pindel, varscan2
- PZP | c.3688dup p.T1230Nfs*10 | Frame Shift Ins (INS) | VAF 30/79 reads (38%) | called by mutect2, pindel, varscan2
- SDS | c.500del p.V167Gfs*59 | Frame Shift Del (DEL) | VAF 34/90 reads (38%) | called by mutect2, pindel, varscan2
- SLC30A2 | c.699dup p.K234Qfs*4 | Frame Shift Ins (INS) | VAF 20/62 reads (32%) | called by mutect2, pindel, varscan2
- SPRED2 | c.20del p.P7Qfs*15 | Frame Shift Del (DEL) | VAF 14/86 reads (16%) | called by mutect2, pindel, varscan2
- TMEM202 | c.437del p.S146Tfs*2 | Frame Shift Del (DEL) | VAF 45/111 reads (41%) | called by mutect2, pindel, varscan2
- ACO1 | c.2185T>C p.L729= | Silent (SNP) | VAF 48/171 reads (28%) | catalogued as COSV100008476; called by muse, mutect2, varscan2
- ADAMTS13 | c.2223C>T p.P741= | Silent (SNP) | VAF 47/66 reads (71%) | catalogued as rs1470057391, COSV100747170; called by muse, mutect2, varscan2
- ADRA1A | c.1267C>A p.R423= | Silent (SNP) | VAF 71/153 reads (46%) | catalogued as COSV99369834; called by muse, mutect2, varscan2
- AIRE | c.1554C>T p.S518= | Silent (SNP) | VAF 21/124 reads (17%) | catalogued as rs1432714738, COSV52397493; called by muse, mutect2, varscan2
- AMPD1 | c.708C>T p.N236= | Silent (SNP) | VAF 56/141 reads (40%) | catalogued as COSV100815177; called by muse, mutect2, varscan2
- APCDD1L | c.999C>A p.A333= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV100954046; called by muse, mutect2, varscan2
- ATP2B2 | c.3354G>C p.L1118= (on ENST00000352432; = p.L1084= on NM_001683.5) | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100660307; called by muse, mutect2
- ATP2B3 | c.711C>T p.L237= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV99685418; called by muse, mutect2, varscan2
- C1R | c.735C>A p.T245= (on ENST00000536053 / NM_001354346.2; = p.T231= on NM_001733.7) | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as COSV101599223; called by muse, mutect2, varscan2
- C1orf141 | c.429A>T p.P143= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV100924371; called by muse, mutect2, varscan2
- CACNA1E | c.3024G>T p.L1008= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100704487; called by muse, mutect2, varscan2
- CACNA1E | c.5958T>A p.P1986= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100704491; called by muse, mutect2, varscan2
- CACNA1S | c.2721C>G p.A907= | Silent (SNP) | VAF 91/161 reads (57%) | catalogued as rs1158348726, COSV100755240; called by muse, mutect2, varscan2
- CAMTA1 | c.1380G>T p.V460= | Silent (SNP) | VAF 46/120 reads (38%) | catalogued as COSV100351857; called by muse, mutect2, varscan2
- CASP5 | c.849G>C p.P283= | Silent (SNP) | VAF 62/152 reads (41%) | catalogued as rs113183781, COSV99507971; called by muse, mutect2, varscan2
- CCDC74B | c.501C>G p.L167= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs1321190744, COSV100134633; called by muse, mutect2, varscan2
- CCER1 | c.663G>A p.V221= | Silent (SNP) | VAF 43/193 reads (22%) | catalogued as COSV100727124; called by muse, mutect2, varscan2
- CDH12 | c.504T>A p.T168= | Silent (SNP) | VAF 50/180 reads (28%) | catalogued as COSV101203139; called by muse, mutect2, varscan2
- CDH9 | c.1957C>A p.R653= | Silent (SNP) | VAF 54/138 reads (39%) | catalogued as COSV50320975, COSV99142080; called by muse, mutect2, varscan2
- CDK5R2 | c.1005C>T p.G335= | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as rs2230642, COSV100225968; called by muse, varscan2
- CHD2 | c.249A>G p.K83= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as rs990673547, COSV100560839; called by muse, mutect2, varscan2
- CLCA4 | c.849A>G p.K283= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV55369228; called by muse, mutect2, varscan2
- COG6 | c.927A>T p.G309= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV100743213; called by muse, mutect2, varscan2
- COL22A1 | c.423C>A p.A141= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100279924; called by muse, mutect2
- COL27A1 | c.4935A>G p.P1645= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV61932182; called by muse, mutect2, varscan2
- COL6A3 | c.954G>A p.E318= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV99800415; called by muse, mutect2, varscan2
- COL6A5 | c.7416C>A p.T2472= (on ENST00000312481; = p.T2468= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/58 reads (53%) | catalogued as COSV99594146; called by muse, mutect2, varscan2
- COL6A6 | c.363A>C p.A121= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV100650726; called by muse, mutect2, varscan2
- COLEC12 | c.156C>T p.I52= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV101232128; called by muse, mutect2, varscan2
- CORO7 | c.1836G>T p.S612= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as COSV99228007; called by muse, mutect2, varscan2
- CROCC | c.4677G>T p.A1559= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100978351; called by muse, mutect2, varscan2
- CYP2D6 | c.1401G>T p.S467= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs1135832, COSV100637356; called by muse, mutect2, varscan2
- DAB1 | c.591G>C p.V197= | Silent (SNP) | VAF 9/181 reads (5%) | catalogued as COSV100140598; called by muse, mutect2
- DACH1 | c.945T>A p.P315= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as COSV100498995; called by muse, mutect2, varscan2
- DENND4B | c.3243G>C p.L1081= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100768839; called by mutect2, varscan2
- DLEC1 | c.1881G>T p.R627= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV100343139; called by muse, mutect2, varscan2
- DRD2 | c.48G>A p.Q16= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as COSV100669979; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.405G>A p.E135= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as COSV99143722; called by muse, mutect2, varscan2
- EHD3 | c.273G>A p.E91= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV100434830, COSV59033348; called by muse, mutect2, varscan2
- ENTHD1 | c.1326C>T p.A442= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs768337439, COSV100289002, COSV57321245; called by muse, mutect2, varscan2
- F13B | c.921G>A p.E307= | Silent (SNP) | VAF 27/164 reads (16%) | catalogued as COSV66373028; called by muse, mutect2, varscan2
- F5 | c.1089T>C p.Y363= | Silent (SNP) | VAF 67/240 reads (28%) | catalogued as rs1255063409, COSV63121191; called by muse, mutect2, varscan2
- GPR162 | c.198C>A p.P66= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as COSV50589117, COSV99163859; called by muse, mutect2, varscan2
- HAS2 | c.1560A>T p.A520= | Silent (SNP) | VAF 87/196 reads (44%) | catalogued as COSV100392090; called by muse, varscan2
- IGSF1 | c.3903G>A p.Q1301= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as COSV100812235; called by muse, mutect2, varscan2
- IL13RA2 | c.39C>A p.T13= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV99683282; called by muse, mutect2, varscan2
- IL15 | c.309A>T p.G103= | Silent (SNP) | VAF 55/84 reads (65%) | catalogued as COSV99650756; called by muse, mutect2, varscan2
- IL18RAP | c.1404G>T p.V468= | Silent (SNP) | VAF 70/130 reads (54%) | catalogued as COSV99962272; called by muse, mutect2, varscan2
- INTS10 | c.1635A>G p.R545= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV101208725; called by muse, mutect2, varscan2
- ITGBL1 | c.1125C>G p.V375= | Silent (SNP) | VAF 26/137 reads (19%) | catalogued as COSV101095598; called by muse, mutect2, varscan2
- KALRN | c.2196C>A p.P732= | Silent (SNP) | VAF 98/204 reads (48%) | catalogued as COSV99566501; called by muse, mutect2, varscan2
- KCNA5 | c.1218G>T p.R406= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99364090; called by muse, mutect2, varscan2
- KCNMA1 | c.318G>A p.L106= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99698947; called by muse, mutect2, varscan2
- KIAA1549 | c.5229G>T p.T1743= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV54303760, COSV54309135; called by muse, mutect2, varscan2
- KIF1B | c.3756C>T p.L1252= (on ENST00000377086 / NM_001365952.1; = p.L1206= on NM_015074.3) | Silent (SNP) | VAF 30/60 reads (50%) | catalogued as COSV55804300; called by muse, mutect2, varscan2
- KRT72 | c.651G>A p.V217= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as COSV53374444; called by muse, mutect2, varscan2
- LCOR | c.1146G>A p.E382= | Silent (SNP) | VAF 36/78 reads (46%) | catalogued as COSV99617075; called by muse, mutect2, varscan2
- LENG8 | c.2043G>A p.T681= | Silent (SNP) | VAF 7/195 reads (4%) | catalogued as rs775744959, COSV100418154; called by muse, mutect2
- MFSD6L | c.729G>A p.R243= | Silent (SNP) | VAF 38/83 reads (46%) | catalogued as COSV61006377; called by muse, mutect2, varscan2
- MIB1 | c.2223A>G p.G741= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as COSV99839253; called by muse, mutect2, varscan2
- MISP | c.945G>A p.Q315= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as COSV99297059; called by muse, mutect2, varscan2
- MS4A4A | c.717T>A p.V239= | Silent (SNP) | VAF 44/109 reads (40%) | catalogued as COSV100557893; called by muse, mutect2, varscan2
- MTR | c.3330G>A p.L1110= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV100855496; called by muse, mutect2
- MUC16 | c.8904T>A p.P2968= | Silent (SNP) | VAF 57/97 reads (59%) | catalogued as COSV101200761; called by muse, mutect2, varscan2
- MXRA5 | c.7716C>A p.P2572= | Silent (SNP) | VAF 8/11 reads (73%) | catalogued as COSV54229411; called by muse, mutect2, varscan2
- MYT1L | c.2907C>A p.S969= | Silent (SNP) | VAF 79/151 reads (52%) | catalogued as COSV101217326; called by muse, mutect2, varscan2
- NEB | c.7695C>A p.A2565= | Silent (SNP) | VAF 232/395 reads (59%) | catalogued as COSV99426254; called by muse, mutect2, varscan2
- NETO2 | c.1068G>T p.G356= | Silent (SNP) | VAF 42/72 reads (58%) | catalogued as COSV100292558; called by muse, mutect2, varscan2
- NF1 | c.127C>T p.L43= | Silent (SNP) | VAF 25/71 reads (35%) | catalogued as rs1060503913, CD040910, CD1311303, COSV100647931, COSV62200385; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOTCH3 | c.3171G>T p.A1057= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as COSV99658370; called by muse, mutect2, varscan2
- NPR2 | c.1716A>G p.R572= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100709646; called by muse, mutect2, varscan2
- ODF2 | c.2268G>A p.T756= (on ENST00000434106 / NM_153433.2; = p.T732= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 91/124 reads (73%) | catalogued as rs376287856; called by muse, mutect2, varscan2
- OR10K1 | c.348A>T p.A116= | Silent (SNP) | VAF 26/199 reads (13%) | catalogued as COSV99193837; called by muse, mutect2, varscan2
- OR8H2 | c.852G>A p.V284= | Silent (SNP) | VAF 34/141 reads (24%) | catalogued as COSV100542439; called by muse, mutect2, varscan2
- PCDH11X | c.2358G>A p.V786= | Silent (SNP) | VAF 45/70 reads (64%) | catalogued as COSV53494767; called by muse, mutect2, varscan2
- PCDHA2 | c.40C>A p.R14= | Silent (SNP) | VAF 39/91 reads (43%) | catalogued as rs781937670, COSV100974091, COSV65371659; called by muse, mutect2, varscan2
- PCDHA2 | c.873T>C p.T291= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as COSV100974092; called by muse, mutect2, varscan2
- PCDHA3 | c.1245C>A p.R415= | Silent (SNP) | VAF 115/294 reads (39%) | catalogued as COSV100793653, COSV63540533; called by muse, mutect2, varscan2
- PCDHA6 | c.327C>A p.I109= | Silent (SNP) | VAF 72/325 reads (22%) | catalogued as rs1240977391, COSV100972480, COSV65349761; called by muse, mutect2, varscan2
- PCDHB16 | c.2007C>T p.P669= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as COSV99502582; called by muse, mutect2, varscan2
- PCDHB6 | c.1470G>T p.P490= | Silent (SNP) | VAF 114/317 reads (36%) | catalogued as COSV50702389, COSV99170684; called by muse, mutect2, varscan2
- PCDHB7 | c.1740C>A p.A580= | Silent (SNP) | VAF 33/190 reads (17%) | catalogued as rs781920350, COSV99177223, COSV99177230; called by muse, mutect2, varscan2
- PCK2 | c.639C>T p.S213= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs890165002, COSV99394051; called by muse, mutect2, varscan2
- PDE3A | c.1476C>A p.S492= | Silent (SNP) | VAF 35/101 reads (35%) | catalogued as COSV100762625, COSV100762655; called by muse, mutect2, varscan2
- PERP | c.135C>T p.S45= | Silent (SNP) | VAF 29/120 reads (24%) | catalogued as COSV101408601; called by muse, mutect2, varscan2
- PLK3 | c.630G>A p.L210= | Silent (SNP) | VAF 7/91 reads (8%) | catalogued as COSV100221246; called by muse, mutect2
- PRAMEF15 | c.723C>A p.L241= | Silent (SNP) | VAF 102/550 reads (19%) | called by muse, mutect2, varscan2
- PRDM2 | c.192A>G p.K64= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as COSV99342446; called by muse, mutect2, varscan2
- PRKCE | c.1644G>T p.L548= | Silent (SNP) | VAF 108/220 reads (49%) | catalogued as COSV100079046; called by muse, mutect2, varscan2
- PROSER2 | c.240G>C p.V80= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV99508954; called by muse, mutect2, varscan2
- PROX1 | c.84G>C p.G28= | Silent (SNP) | VAF 52/86 reads (60%) | catalogued as COSV99799994; called by muse, mutect2, varscan2
- PSG1 | c.504C>A p.T168= | Silent (SNP) | VAF 138/454 reads (30%) | catalogued as COSV99741055; called by muse, mutect2, varscan2
- PTCD3 | c.1722C>G p.T574= | Silent (SNP) | VAF 91/223 reads (41%) | catalogued as COSV99606551; called by muse, mutect2, varscan2
- PTPN5 | c.381G>T p.L127= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as COSV100659957; called by muse, mutect2, varscan2
- PTPRO | c.1299C>G p.T433= | Silent (SNP) | VAF 19/60 reads (32%) | catalogued as COSV99841367; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2046G>A p.K682= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV99770369; called by muse, mutect2, varscan2
- RBM12 | c.837G>A p.P279= | Silent (SNP) | VAF 73/106 reads (69%) | catalogued as rs140930448; called by muse, mutect2, varscan2
- RELN | c.7257G>T p.V2419= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV100634489; called by muse, mutect2, varscan2
- RNF213 | c.10899C>A p.T3633= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV100301223; called by muse, mutect2
- RPS8 | c.567G>T p.V189= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100785496; called by muse, mutect2, varscan2
- RYR1 | c.5487C>A p.P1829= | Silent (SNP) | VAF 48/294 reads (16%) | catalogued as rs145224633, COSV100616594; called by muse, mutect2, varscan2
- S100A7L2 | c.162C>T p.Y54= | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as COSV100906912; called by muse, mutect2, varscan2
- SALL3 | c.1578G>C p.V526= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV101610036; called by muse, mutect2
- SCN3A | c.366C>A p.I122= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs372269218; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCUBE1 | c.1299C>A p.S433= | Silent (SNP) | VAF 64/107 reads (60%) | catalogued as COSV100683571; called by muse, mutect2, varscan2
- SEMA3F | c.1539C>T p.V513= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV99137774; called by muse, mutect2, varscan2
- SEMA4F | c.210G>A p.V70= | Silent (SNP) | VAF 78/167 reads (47%) | catalogued as COSV100336099; called by muse, mutect2, varscan2
- SERPINB8 | c.708G>T p.T236= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99729335; called by muse, mutect2, varscan2
- SIGLEC12 | c.255G>T p.V85= | Silent (SNP) | VAF 84/210 reads (40%) | catalogued as COSV99389523; called by muse, mutect2, varscan2
- SLC7A3 | c.118C>T p.L40= | Silent (SNP) | VAF 18/23 reads (78%) | catalogued as COSV99979731; called by muse, mutect2, varscan2
- SNTG1 | c.714G>T p.G238= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as rs1261208572, COSV99385338; called by muse, mutect2, varscan2
- SPDYE5 | c.765C>A p.A255= | Silent (SNP) | VAF 74/189 reads (39%) | called by muse, mutect2, varscan2
- SPEF2 | c.4392G>T p.L1464= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV100289294, COSV57432747; called by muse, mutect2, varscan2
- SPTBN5 | c.1335A>C p.A445= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100311987; called by muse, mutect2
- SULT1B1 | c.783G>T p.T261= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as COSV100150427; called by muse, mutect2, varscan2
- TACC2 | c.5931A>G p.P1977= (on ENST00000334433; = p.P55= on NM_006997.4) | Silent (SNP) | VAF 31/105 reads (30%) | catalogued as rs1432963606, COSV99587454; called by muse, mutect2, varscan2
- TAF1C | c.2361C>T p.P787= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs1287754206, COSV100499751; called by muse, mutect2, varscan2
- TECTA | c.4521C>A p.A1507= | Silent (SNP) | VAF 20/48 reads (42%) | catalogued as COSV50728824, COSV50803726; called by muse, mutect2, varscan2
- TG | c.7224G>T p.R2408= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as COSV99601884, COSV99602475; called by muse, mutect2, varscan2
- TIAM1 | c.3663C>A p.I1221= | Silent (SNP) | VAF 47/84 reads (56%) | catalogued as COSV99737876; called by muse, mutect2, varscan2
- TMEM225 | c.249C>A p.I83= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV100902861; called by muse, mutect2, varscan2
- TNS2 | c.3237G>T p.L1079= (on ENST00000314250 / NM_170754.4; = p.L1089= on NM_015319.2) | Silent (SNP) | VAF 45/96 reads (47%) | catalogued as COSV100036852; called by muse, mutect2, varscan2
- TSPY2 | c.123G>A p.R41= | Silent (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- TSSK1B | c.984C>T p.P328= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as rs759817547, COSV101181155; called by muse, mutect2, varscan2
- UBA7 | c.1918C>T p.L640= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV100323720; called by muse, mutect2, varscan2
- UGGT1 | c.2877A>G p.K959= | Silent (SNP) | VAF 4/84 reads (5%) | catalogued as COSV99391014; called by muse, mutect2
- VN1R5 | c.567C>A p.P189= | Silent (SNP) | VAF 22/312 reads (7%) | called by muse, mutect2
- WDR24 | c.1242C>G p.R414= (on ENST00000248142; = p.R284= on NM_032259.4) | Silent (SNP) | VAF 34/57 reads (60%) | catalogued as COSV99555921; called by muse, mutect2, varscan2
- XIRP2 | c.288G>C p.L96= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV99740509, COSV99746056; called by muse, mutect2, varscan2
- ZNF284 | c.1557A>T p.G519= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV101399062; called by muse, mutect2, varscan2
- ZNF516 | c.978G>T p.V326= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV101487347; called by muse, mutect2, varscan2
- AP004606.1 | chr11:133532265 T>C | 5'Flank (SNP) | VAF 11/35 reads (31%) | catalogued as COSV101587920; called by muse, mutect2, varscan2
- C2orf83 | n.516T>C | RNA (SNP) | VAF 28/182 reads (15%) | catalogued as COSV100018197; called by muse, mutect2
- CEP295 | chr11:93735187 A>T | 3'Flank (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+11911G>T | Intron (SNP) | VAF 51/104 reads (49%) | catalogued as COSV100456788, COSV58342945; called by muse, mutect2, varscan2
- FRMPD2B | n.886C>G | RNA (SNP) | VAF 71/381 reads (19%) | called by muse, mutect2, varscan2
- MIR206 | n.34dup | RNA (INS) | VAF 31/68 reads (46%) | called by mutect2, pindel, varscan2
- PHACTR4 | c.17-20698G>A | Intron (SNP) | VAF 21/74 reads (28%) | catalogued as COSV100868485; called by muse, mutect2, varscan2
- RPL23A | c.26-149G>C | Intron (SNP) | VAF 12/119 reads (10%) | catalogued as COSV99411854; called by muse, mutect2, varscan2
- SNORD114-6 | n.17del | RNA (DEL) | VAF 9/22 reads (41%) | called by pindel*, varscan2
